Surgical pathology report (de-identified scan), TCGA case TCGA-HE-A5NH, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-HE-A5NH-01A (Primary Tumor).

Sample Number

Sample Type TUMOUR

Diagnosis	Renal cell carcinoma, papillary type (types 1 and 2)
Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	
Type of Procedure	RESECT
Site of Tissue/Primary (Histology)	Left kidney
Tumour Size (cm)	3
Histology	Renal cell carcinoma, papillary type (types 1 and 2)
Grade/Differentiation	III
Pathological T	T1a
Pathological N	NX
Clinical M	M0
Histology Comments	Grade/Diff: Fuhrman grade 3/4.

Sample Number

Sample Type BUFFY

Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	

ICD-O-3

Carcinoma, papillary renal cell 8260/3

Site ④ Kidney N6S C64.9

Jaw 2/11/13

Criteria	W 2/7/13	Yes	No
ICD-O Discrepancy			✓

Source: NCI Genomic Data Commons file 03174138-27f2-4425-a39c-dbaf95adc14a (TCGA-HE-A5NH.E24C3E1C-D148-4C68-A691-CD1AF8014C4B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).